Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A4II, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A4II-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Pharyngeal wall lesion, posterior, partial pharyngectomy

Tumor histologic type/subtype: squamous cell carcinoma, well differentiated

Primary site: oropharynx

1CD-0-3

Size: 2.2 cm

carcinoma, squamous cell, NOS 8070/3

Site: oropharynx, NOS C10.9

Extent of invasion:

Angiolymphatic invasion: not identified

Perineural Invasion: not identified

Bone invasion: not identified

*pw
10/3/12*

Carcinoma in situ: present, 0.2 cm from the green superior inked margin

Surgical Margins: Free of tumor: invasive carcinoma comes to within 0.6 cm of the black medial margin, 0.5 cm of the green superior margin, 0.8 cm from the lateral margin, and grossly <0.7 cm from the yellow inferior margin.

AJCC PATHOLOGIC TNM STAGE: pT2 pNx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Soft tissue, lateral margin, biopsy

- Benign squamous mucosa and lymphoid tissue

C: Soft tissue, anterior floor of mouth lesion, biopsy

- Benign squamous mucosa

D: Soft tissue, floor of mouth lesion, biopsy

- Invasive squamous cell carcinoma, well differentiated

- Carcinoma extends to inked cauterized margins

E: Soft tissue, posterior margin, floor of mouth lesion, biopsy

- Invasive squamous cell carcinoma with marked cautery artifact

[page 2 of 3]
F: Soft tissue, gingiva, biopsy
- Invasive squamous cell carcinoma, well differentiated

Clinical History:

-year-old male with throat cancer who presents for radical pharyngectomy, excision of floor of mouth lesion.

Gross Description:

Received are six appropriately labeled containers.

Container A is additionally labeled "posterior pharyngeal wall lesion, stitch is lateral" and holds a roughly rectangular shaped piece of tan/pink mucosa oriented as stated above. The specimen is 3.3 cm from superior to inferior, 2.7 cm from lateral to medial, and up to 1.3 cm from superficial to deep. The margins are differentially inked lateral edge blue, superior edge green, inferior edge yellow, and medial and deep margins, black. On the surface there is a 2.2 x 2.1 cm tan raised soft somewhat circumscribed lesion. The lesion comes to within 0.5 cm of the black inked medial margin, green inked superior margin, and is 0.3 cm from the blue inked lateral margin, and is >0.7 cm from the yellow inked inferior margin. The specimen is sectioned from lateral towards medial to reveal that the lesion extends 0.3 cm into the underlying soft tissue, and to within 0.6 cm of the black inked deep margin.

Block Summary:

A1-A2 - Lateral margin, perpendicular

A3-A7 - Sequential sections moving from lateral towards medial to include superior, inferior, and deep margins, perpendicular

A8 - Medial edge of specimen, en face,

Tumor is submitted to tissue procurement.

Container B is additionally labeled "lateral margin." It holds a piece of tan glistening mucosa, 2.0 x 0.6 x 0.4 cm. The surgical margin is inked black. The specimen is serially sectioned perpendicular to the black inked surface and submitted in block B1,

Container C is additionally labeled "anterior margin, floor of mouth lesion." It holds a 4 x 4 x 4 mm tan soft tissue fragment; block C1,

[page 3 of 3]
Container D is additionally labeled "floor of mouth lesion." It holds a 1.6 x 0.6 x 0.4 cm tan/red soft tissue fragment. One surface is cauterized and inked black. The specimen is sectioned perpendicular to the black inked surface and submitted in block D1,

Container E is additionally labeled "posterior margin, floor of mouth lesion." It holds a 1.0 x 0.4 x 0.4 cm red/tan soft tissue fragment. One edge is cauterized and inked black. The specimen is sectioned perpendicular to the black inked edge and submitted in block E1,

Container F is additionally labeled "gingiva." It holds three pieces of tan soft tissue, 6 x 5 x 4 mm in aggregate. (Block F1,

Dual/Synchronous Primary Notes	HNSC	X

10/3/12

Source: NCI Genomic Data Commons file ba8449ac-1657-4ea1-b565-ebc30765de96 (TCGA-BA-A4II.1C768398-4A3C-4F5C-9E17-828102379885.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).